Somatic mutation profile of tumor specimen 0DU3KS from CCDI case PBCKPA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.1 years (5,879 days).
Specimen 0DU3KS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cab2a15c-b083-49e8-ba6c-e163c8a79c63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU3MT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78ee1f6d-333a-46c8-a666-d786176e1df0

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 5'UTR 1, Silent 1, Missense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NHS | c.2827_2830del p.S943Ifs*104 | Frame Shift Del (DEL) | VAF 196/1710 reads (11%) | called by pindel, varscan2
- PTPN9 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 76/570 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); called by muse, varscan2
- RHOU | c.603C>A p.I201= | Silent (SNP) | VAF 240/2156 reads (11%) | called by muse, varscan2
- CFHR4 | c.-47A>T | 5'UTR (SNP) | VAF 88/816 reads (11%) | called by muse, varscan2
